FM case AD10333 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/411db10b-e285-463a-aab3-8813000f7547

Female, 75.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the rectum; primary biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
